Gene-level copy-number profile of tumor specimen TCGA-CA-6719-01A from TCGA case TCGA-CA-6719, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Descending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.6 years (28,343 days).
Specimen TCGA-CA-6719-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.abd67881-285a-4f32-a1a3-12960b57c306.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CA-6719-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/94579185-2191-4653-a6d9-0565e0b5436d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,696; copy number 2: 7,959; copy number 3: 28,186; copy number 4: 13,601; copy number 5: 6,255; copy number 6: 640; copy number 7: 1,464; copy number 8: 10; copy number 16: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CA-6719-01A-11D-1834-01): tumor purity 0.57, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,476 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,329,288–56,070,513, 6 genes, copy number 7 (within-gene range 3–8): AL603840.1, GOT2P1, MTCO2P34, RN7SKP291, RNU6-830P, Y_RNA.
- chr1:56,145,721–56,715,335, 10 genes, copy number 8 (within-gene range 3–8): AL353681.1, AC119674.1, AC119674.2, RPSAP20, LINC01767, PLPP3, RPL21P23, RPL23AP85, AC099789.1, PRKAA2.
- chr6:61,679,961–62,286,225, 2 genes, copy number 16: KHDRBS2, AL355347.1.
- chr20:87,250–64,313,132, 1,458 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,271. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
